Somatic mutation profile of tumor specimen TCGA-DQ-7593-01A (aliquot TCGA-DQ-7593-01A-11D-2229-08) from TCGA case TCGA-DQ-7593, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Tumor grade: G4; Age at diagnosis: 58.7 years (21,439 days).
Specimen TCGA-DQ-7593-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72e904da-717c-4697-9dbb-ea1f5808d540.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DQ-7593-10D (Blood Derived Normal), aliquot TCGA-DQ-7593-10D-01D-2229-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/518aa26c-ba77-438e-9a51-8ddf0df8ba1f

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 2, Translation Start Site 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BLNK | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99814109; called by muse, mutect2, varscan2
- CARD11 | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV100712261; called by muse, mutect2, varscan2
- DNAH9 | c.7162C>A p.Q2388K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs1273809007, COSV52367310, COSV99307182; called by muse, mutect2
- FMN2 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100146629; called by muse, varscan2
- IGHV3-35 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 54/379 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.736); catalogued as rs765476090; called by muse, mutect2, varscan2
- KIAA1109 | c.355C>A p.H119N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as COSV99169327; called by muse, mutect2
- KMT2D | c.8320C>T p.R2774W | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs779166504, COSV56489587, COSV99984510; called by muse, varscan2
- PCDHGA10 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 69/788 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.255); catalogued as rs541492590, COSV99543285; called by muse, mutect2
- RBM47 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 21/181 reads (12%) | catalogued as COSV99921259; called by muse, mutect2, varscan2
- SH3GLB2 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs1045622036, COSV65332159; called by muse, mutect2, varscan2
- SLC9A2 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.432); catalogued as COSV99296585; called by muse, mutect2, varscan2
- TTN | c.60676G>A p.V20226M (on ENST00000591111; = p.V12802M on NM_003319.4) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | PolyPhen benign (0.313); catalogued as rs769884849, COSV100623141; called by muse, mutect2
- UTP20 | c.4813T>A p.S1605T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.063); catalogued as COSV99882202; called by muse, mutect2, varscan2
- CYLD | c.2797_2798dup p.C934Afs*20 | Frame Shift Ins (INS) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- WDR11 | c.1556+4_1556+7del p.X519_splice | Splice Site (DEL) | VAF 14/60 reads (23%) | called by pindel, varscan2
- CILP2 | c.249C>T p.Y83= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1217752844, COSV99365026; called by muse, mutect2
- DENND4C | c.888G>A p.T296= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs757295123, COSV100991508; called by muse, mutect2, varscan2
- DIRAS2 | c.534C>T p.I178= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as rs904283931, COSV65369952; called by muse, mutect2
- EVC | c.2625C>T p.H875= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs764729655, COSV99382282; called by muse, mutect2, varscan2
- H4C8 | c.297C>T p.Y99= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as rs1228229961, COSV99175500; called by muse, mutect2, varscan2
- MS4A4A | c.9G>A p.Q3= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs944001506, COSV100557881; called by muse, mutect2, varscan2
